Gene-level copy-number profile of tumor specimen ALCH-B4NO-TTP1-A from ALCHEMIST case ALCH-B4NO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,394 days).
Specimen ALCH-B4NO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8706df09-f3a8-43ad-a27e-64ac45ed8df3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4NO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/ec307aab-1e81-40f8-99e6-13a641241f4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,114; copy number 2: 52,187; copy number 3: 3,782; copy number 4: 35; copy number 5: 31; copy number 6: 85; copy number 7: 26; copy number 8: 61; copy number 9: 17; copy number 10: 22; copy number 11: 27; copy number 12: 1; copy number 14: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 272 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–5,320,304, 108 genes, copy number 5–11 (broad region; genes not listed).
- chr5:6,839,460–8,685,816, 41 genes, copy number 7–9: LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4.
- chr5:8,754,869–16,617,058, 107 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:75,092,573–75,149,817, 1 gene, copy number 8: GTF2IRD2B.
- chr7:75,391,955–75,395,434, 1 gene, copy number 20 (within-gene range 3–20): AC211486.1.
- chr8:12,064,389–12,099,536, 3 genes, copy number 5–6: DEFB130B, RNA5SP253, DEFB108D.
- chr10:44,488,335–44,488,445, 1 gene, copy number 5: AL356157.2.
- chr10:95,141,925–95,168,425, 1 gene, copy number 5: AL157834.4.
- chr11:1,947,278–1,993,670, 3 genes, copy number 5–10: MRPL23, MRPL23-AS1, LINC01219.
- chr11:90,017,611–90,024,511, 1 gene, copy number 9: AP004607.6.
- chr14:36,136,108–36,176,468, 1 gene, copy number 5 (within-gene range 2–5): PTCSC3.
- chr16:28,802,743–28,817,828, 1 gene, copy number 10 (within-gene range 3–10): AC145285.2.
- chr16:33,548,297–33,554,408, 1 gene, copy number 12: AC136944.4.
- chr20:45,648,563–45,670,270, 1 gene, copy number 6: WFDC11.
- chr21:43,169,008–43,172,805, 1 gene, copy number 14: CRYAA.

Autosomal genes at a single copy (total copy number 1): 1,769. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
